Somatic mutation profile of tumor specimen TCGA-AR-A24W-01A (aliquot TCGA-AR-A24W-01A-11D-A17G-09) from TCGA case TCGA-AR-A24W, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.1 years (20,123 days).
Specimen TCGA-AR-A24W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 269b4c7d-4921-4865-85b7-d77e98a1e09b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24W-10A (Blood Derived Normal), aliquot TCGA-AR-A24W-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10eee493-18ab-46b8-9339-54e1654ab607

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY7 | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs967639581, COSV54268562; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs184507640, COSV58445036; called by muse, mutect2, varscan2
- ATP13A4 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV55071914; called by muse, mutect2, varscan2
- BNC2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV66151608; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.688); catalogued as COSV65442835; called by muse, mutect2, varscan2
- MACF1 | c.5980A>T p.M1994L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99243237; called by muse, mutect2
- NBAS | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as COSV99868679; called by muse, mutect2
- NDUFAF2 | c.222G>T p.W74C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99681274; called by muse, mutect2
- PANX1 | c.1217G>A p.S406N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1246752490, COSV99921748; called by muse, mutect2
- PRKAA2 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV100982786, COSV100983094; called by muse, mutect2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as rs146650273; called by pindel, varscan2
- EVPL | c.3322C>A p.Q1108K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- FOXG1 | c.564G>T p.A188= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100486676, COSV100486912; called by muse, mutect2
- WSCD2 | c.1140C>T p.N380= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99774417; called by muse, mutect2
- PRR12 | chr19:49594951 G>A | 5'Flank (SNP) | VAF 7/23 reads (30%) | catalogued as rs746376324, COSV55870130, COSV55870202; called by muse, mutect2, varscan2
